Somatic mutation profile of tumor specimen TARGET-10-PATXKW-03A (aliquot TARGET-10-PATXKW-03A-01D) from TARGET case TARGET-10-PATXKW, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 18.2 years (6,640 days).
Specimen TARGET-10-PATXKW-03A: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 94487f88-8b15-45e4-9379-5fbe764eb031.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PATXKW-10A (Blood Derived Normal), aliquot TARGET-10-PATXKW-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/71d7f4b9-3bff-42d3-ba97-db3231a6d171

The open-access MAF lists 17 somatic variants for this specimen: 11 protein-altering or splice-affecting, 3 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, Frame Shift Ins 3, Silent 3, Intron 2, Frame Shift Del 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GNAI2 | c.536G>A p.R179H | Missense Mutation (SNP) | VAF 28/65 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs137853227, COSV56492718; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 7/48 reads (15%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.339); catalogued as rs121913237, COSV54736383, COSV54736555, COSV54736974; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- GRM1 | c.574C>G p.L192V | Missense Mutation (SNP) | VAF 45/108 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.072); catalogued as COSV51383105; called by muse, mutect2, varscan2
- MYH2 | c.5002C>T p.R1668W | Missense Mutation (SNP) | VAF 34/66 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs569489518, COSV55431886, COSV55435762; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RTTN | c.755C>T p.S252L | Missense Mutation (SNP) | VAF 29/70 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.32); catalogued as rs372558548; called by muse, mutect2, varscan2
- SEC14L3 | c.1096G>A p.D366N | Missense Mutation (SNP) | VAF 21/32 reads (66%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.937); catalogued as rs140616097; called by muse, mutect2, varscan2
- SETD2 | c.5764_5765insTT p.E1922Vfs*24 | Frame Shift Ins (INS) | VAF 60/169 reads (36%) | catalogued as COSV57455883; called by mutect2, pindel, varscan2
- TMED10 | c.388G>A p.V130M | Missense Mutation (SNP) | VAF 36/72 reads (50%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.908); catalogued as COSV57849406; called by muse, mutect2, varscan2
- UBE2D3 | c.125_126insGGCAC p.D42Efs*13 | Frame Shift Ins (INS) | VAF 4/46 reads (9%) | catalogued as COSV57664847; called by mutect2, pindel*
- WT1 | c.1101_1102dup p.R368Hfs*70 | Frame Shift Ins (INS) | VAF 20/29 reads (69%) | catalogued as COSV60065714, COSV60066671, COSV60067526, COSV60073219, COSV60075996, COSV60077962, COSV60079089, COSV60085405; called by mutect2, pindel, varscan2
- SETD2 | c.602_608delinsAGGGG p.T201Kfs*35 | Frame Shift Del (DEL) | VAF 17/34 reads (50%) | called by pindel, varscan2*
- CDH6 | c.954C>T p.V318= | Silent (SNP) | VAF 26/44 reads (59%) | catalogued as COSV54067872; called by muse, mutect2, varscan2
- ITGB8 | c.180G>A p.A60= | Silent (SNP) | VAF 11/60 reads (18%) | catalogued as rs370914824; called by muse, mutect2, varscan2
- KCNH6 | c.387C>T p.F129= | Silent (SNP) | VAF 13/22 reads (59%) | catalogued as rs757941229, COSV59001207; called by muse, mutect2, varscan2
- DUSP15 | c.254+11_254+12insTAGG | Intron (INS) | VAF 10/24 reads (42%) | catalogued as COSV54068982; called by mutect2, pindel, varscan2
- PRSS27 | c.237-83G>A | Intron (SNP) | VAF 19/44 reads (43%) | called by muse, mutect2, varscan2
- ZSCAN32 | chr16:3382930 C>T | 3'Flank (SNP) | VAF 16/46 reads (35%) | called by muse, mutect2, varscan2
